Somatic mutation profile of tumor specimen MMRF_2041_1_BM_CD138pos (aliquot MMRF_2041_1_BM_CD138pos_T1_KHS5U_L08088) from MMRF case MMRF_2041, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.0 years (19,344 days).
Specimen MMRF_2041_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea4fb92f-0ab2-41bc-bf5d-d5aa2e62780e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2041_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2041_1_PB_Whole_C2_KHS5U_L08089; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46d4afd2-753c-4ffb-bd94-cae4dee89a11

The open-access MAF lists 1,301 somatic variants for this specimen: 444 protein-altering or splice-affecting, 181 silent, 676 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 378, 3'UTR 343, Intron 194, Silent 181, 5'UTR 63, Nonsense Mutation 41, 5'Flank 28, 3'Flank 26, RNA 22, Splice Region 10, Splice Site 6, Frame Shift Del 4.

Variants (750 of 1,301; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S2 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 62/63 reads (98%) | catalogued as rs1555904878, COSV61306169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs779782680, COSV56016015; called by muse, mutect2, varscan2
- ABCB5 | c.2563G>C p.E855Q (on ENST00000404938 / NM_001163941.2; = p.E410Q on NM_178559.6) | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.248); catalogued as rs747074820, COSV51703776; called by muse, mutect2, varscan2
- ABCG2 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99418594; called by muse, mutect2, varscan2
- ACAN | c.7100G>A p.G2367D (on ENST00000560601 / NM_001369268.1; = p.G2291D on NM_001135.3) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs780006455, COSV61368468; called by muse, mutect2, varscan2
- ACCSL | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66580917; called by muse, mutect2, varscan2
- AL645922.1 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs907804461; called by muse, mutect2, varscan2
- ANO4 | c.2804G>A p.R935H (on ENST00000392977 / NM_001286615.2; = p.R900H on NM_178826.4) | Missense Mutation (SNP) | VAF 148/304 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs143188971; called by muse, mutect2, varscan2
- ASB18 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201441236; called by muse, mutect2, varscan2
- ASIC2 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.069); catalogued as rs750071243; called by muse, mutect2, varscan2
- C1orf56 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs1168065927; called by muse, varscan2
- C3orf22 | c.28C>T p.H10Y | Missense Mutation (SNP) | VAF 136/305 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.376); catalogued as COSV100559566; called by muse, mutect2, varscan2
- C8B | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.335); catalogued as rs965303853; called by muse, mutect2, varscan2
- C9orf152 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as COSV68763075; called by muse, mutect2, varscan2
- CABLES1 | c.932C>G p.S311* (on ENST00000256925 / NM_001100619.2; = p.S46* on NM_138375.2) | Nonsense Mutation (SNP) | VAF 108/263 reads (41%) | catalogued as COSV56935325; called by muse, mutect2, varscan2
- CASQ1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63624190, COSV63624249; called by muse, mutect2, varscan2
- CBX2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV53968703; called by muse, mutect2, varscan2
- CCDC74B | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369369085; called by muse, mutect2, varscan2
- CD1A | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99192405; called by muse, mutect2, varscan2
- CD22 | c.1830G>C p.K610N | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV50049500; called by muse, mutect2, varscan2
- CD3E | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 95/216 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs771841066; called by muse, mutect2, varscan2
- CDC20 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV60522144; called by muse, mutect2, varscan2
- CDH12 | c.1572C>G p.F524L | Missense Mutation (SNP) | VAF 99/205 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66394297; called by muse, mutect2, varscan2
- CDK8 | c.647-1G>C p.X216_splice | Splice Site (SNP) | VAF 69/69 reads (100%) | catalogued as COSV67421992, COSV67423481; called by muse, mutect2, varscan2
- CEP44 | c.508-1G>A p.X170_splice | Splice Site (SNP) | VAF 16/22 reads (73%) | catalogued as rs1413246020, COSV99639552; called by muse, mutect2, varscan2
- CEP63 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 61/127 reads (48%) | catalogued as COSV100133109; called by muse, mutect2, varscan2
- CEP68 | c.2035C>G p.Q679E | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1196023405; called by muse, mutect2, varscan2
- CHL1 | c.1960G>C p.E654Q (on ENST00000397491 / NM_001253387.1; = p.E670Q on NM_006614.4) | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.692); catalogued as COSV56587645; called by muse, mutect2, varscan2
- CLDN11 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.271); catalogued as rs773820919, COSV99290949; called by muse, mutect2, varscan2
- CLEC17A | c.424C>G p.P142A | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as rs1294599423, COSV60427431, COSV60428541; called by muse, mutect2, varscan2
- CLEC4G | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 40/84 reads (48%) | catalogued as rs911372657; called by muse, mutect2, varscan2
- COL12A1 | c.3104G>C p.R1035T | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs766290578; called by muse, mutect2, varscan2
- COL12A1 | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59389885; called by muse, varscan2
- COL19A1 | c.1086G>C p.L362F | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.301); catalogued as COSV100505934, COSV59564451; called by muse, mutect2, varscan2
- COL5A2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs754170105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.5189C>G p.S1730C | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767124099; called by muse, mutect2, varscan2
- CYFIP2 | c.3025G>A p.E1009K (on ENST00000616178 / NM_001291722.2; = p.E984K on NM_014376.4) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); catalogued as COSV59033775; called by muse, mutect2, varscan2
- CYLC1 | c.1434G>C p.K478N | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.829); catalogued as rs752754271, COSV100254687, COSV61413075; called by muse, mutect2, varscan2
- CYP24A1 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326459971; called by muse, mutect2, varscan2
- CYP2W1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1193998445, COSV58270473; called by muse, mutect2, varscan2
- CYP4A11 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs531039219, COSV100152338, COSV60223067; called by muse, mutect2, varscan2
- DCAF16 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.092); catalogued as COSV66384068; called by muse, mutect2, varscan2
- DDB1 | c.3080C>T p.S1027L | Missense Mutation (SNP) | VAF 93/175 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.618); catalogued as rs535718507; called by muse, mutect2, varscan2
- DEGS1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60379980; called by muse, mutect2, varscan2
- DEPDC5 | c.3263C>T p.S1088L (on ENST00000400246; = p.S1157L on NM_014662.5) | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as rs376487148, COSV99836702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGCR8 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.869); catalogued as rs1226736814; called by muse, mutect2
- DGUOK | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 94/173 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs868377068; called by muse, mutect2, varscan2
- DNAH6 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52849271; called by muse, mutect2, varscan2
- DNAH7 | c.5651G>A p.R1884Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs201751336; called by muse, mutect2, varscan2
- DNAI1 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54284718; called by muse, mutect2, varscan2
- DZIP3 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as rs1342472171, COSV64311029; called by muse, mutect2, varscan2
- EIF4G2 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 52/119 reads (44%) | catalogued as COSV100379316; called by muse, mutect2, varscan2
- EP300 | c.6045G>A p.M2015I | Missense Mutation (SNP) | VAF 102/199 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs753072432; called by mutect2, varscan2
- EPRS1 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100859548; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, mutect2, varscan2
- FARP2 | c.1630C>T p.L544F | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV104382741; called by muse, mutect2, varscan2
- FAT1 | c.3286C>T p.R1096* | Nonsense Mutation (SNP) | VAF 51/120 reads (43%) | catalogued as rs1358297166, COSV71672426; called by muse, mutect2
- FAT3 | c.6440C>T p.S2147F | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.968); catalogued as COSV53105911; called by muse, mutect2, varscan2
- FBXO41 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.177); catalogued as rs1490830406; called by muse, mutect2, varscan2
- FZD5 | c.1565G>A p.W522* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as rs1384182128; called by muse, mutect2, varscan2
- GABBR1 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); catalogued as rs1330145406; called by muse, mutect2, varscan2
- GIN1 | c.1507C>T p.L503F | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs1554194092; called by muse, mutect2, varscan2
- GPC5 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 85/85 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1268970301, COSV65614751; called by muse, mutect2, varscan2
- GPR19 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1482339320; called by muse, mutect2, varscan2
- H4C9 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62889659; called by muse, mutect2, varscan2
- HMCN1 | c.3929G>C p.R1310T | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV54881200; called by muse, mutect2, varscan2
- HSPA2 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as COSV99904858; called by muse, mutect2, varscan2
- HSPG2 | c.1691del p.P564Hfs*19 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as COSV65974516; called by mutect2, pindel, varscan2
- IGHV1-69 | c.199A>C p.M67L | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs11558013; called by muse, varscan2
- IGHV2-70 | c.320A>T p.D107V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as rs750213489; called by muse, varscan2
- IGLV3-1 | c.47-2A>C p.X16_splice | Splice Site (SNP) | VAF 68/68 reads (100%) | catalogued as rs181922188; called by muse, varscan2
- IGLV3-1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs371563415; called by muse, mutect2, varscan2
- IKBKB | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV60597575, COSV60598284; called by muse, mutect2, varscan2
- INPP4A | c.2542C>T p.R848W (on ENST00000074304 / NM_001134224.1; = p.R809W on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs773837709, COSV99303890; called by muse, mutect2
- ITPR3 | c.2696C>T p.P899L | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs775573697, COSV100967099; called by muse, mutect2, varscan2
- JMJD1C | c.1717G>C p.D573H | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV67863773, COSV67868367; called by muse, mutect2
- KANSL1 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 139/493 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs1385046346; called by muse, mutect2, varscan2
- KCNK1 | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs893133331; called by muse, mutect2, varscan2
- KCNMB4 | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50690718; called by muse, mutect2, varscan2
- KCNV2 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); catalogued as COSV101172602; called by muse, mutect2, varscan2
- KCTD7 | c.773C>T p.S258L (on ENST00000275532; = p.L271= on NM_153033.5) | Missense Mutation (SNP) | VAF 92/202 reads (46%) | catalogued as rs766332054, COSV51878037; called by muse, mutect2, varscan2
- KDM2B | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555292045, COSV100997640, COSV99058194; called by muse, mutect2, varscan2
- KMT2A | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63283617, COSV63285357; called by muse, mutect2, varscan2
- KRTAP27-1 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 108/219 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.459); catalogued as rs535512831; called by muse, mutect2, varscan2
- LAT2 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs572064316; called by muse, mutect2, varscan2
- LMX1B | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.549); catalogued as CM052894; called by muse, mutect2, varscan2
- LRRC1 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs753887291; called by muse, mutect2, varscan2
- MAN1C1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 50/105 reads (48%) | catalogued as COSV56046836; called by muse, mutect2, varscan2
- MAP3K21 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as COSV64046090; called by muse, mutect2, varscan2
- MAT2A | c.1053G>C p.K351N | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV52087882; called by muse, mutect2, varscan2
- MCTP1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs764728886; called by muse, mutect2, varscan2
- MMP9 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 103/213 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812372, COSV63433977, COSV63434113; called by muse, mutect2, varscan2
- MYMK | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 82/105 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs771726516; called by muse, mutect2, varscan2
- NAPEPLD | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV58522163; called by muse, mutect2, varscan2
- NDUFAF2 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.856); catalogued as COSV99681451; called by muse, mutect2, varscan2
- NINL | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770180886, COSV99625830; called by muse, mutect2, varscan2
- NMT2 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV65383331; called by muse, mutect2, varscan2
- NR3C2 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100679295; called by muse, mutect2, varscan2
- NR3C2 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 75/156 reads (48%) | catalogued as rs1553943305; called by muse, mutect2, varscan2
- OR5R1 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 89/170 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs143356825, COSV100393234; called by muse, mutect2, varscan2
- OSBPL3 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs149871533, COSV57659682; called by muse, varscan2
- PARP9 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs139103040; called by muse, mutect2, varscan2
- PATJ | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV57155594; called by muse, mutect2, varscan2
- PAX3 | c.1117C>G p.P373A | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.119); catalogued as rs1357356043; called by muse, mutect2, varscan2
- PCDH18 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 129/242 reads (53%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.575); catalogued as rs1373650094, COSV61272363; called by muse, mutect2, varscan2
- PHF11 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV100710662; called by muse, mutect2, varscan2
- PHLPP1 | c.3474G>C p.K1158N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV53040277; called by muse, mutect2, varscan2
- PNOC | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV57284002; called by muse, mutect2, varscan2
- POLR1A | c.4109G>A p.R1370Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs772119115, COSV55688835; called by muse, mutect2, varscan2
- POU1F1 | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100622711; called by muse, mutect2, varscan2
- PRDM1 | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 62/126 reads (49%) | catalogued as COSV100959009; called by muse, mutect2, varscan2
- PRICKLE3 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 97/101 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782064424, COSV66235388; called by muse, mutect2, varscan2
- PTCHD4 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV59783767; called by muse, mutect2, varscan2
- PTGDS | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as rs192576424, COSV56400546; called by muse, mutect2, varscan2
- QARS1 | c.1864-4C>G | Splice Region (SNP) | VAF 9/18 reads (50%) | catalogued as rs779126108; called by muse, mutect2, varscan2
- RABGAP1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100438357; called by muse, mutect2, varscan2
- RAD51C | c.853C>G p.Q285E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61677447; called by muse, mutect2, varscan2
- RAD52 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.412); catalogued as rs1467957407; called by muse, varscan2
- RBMXL2 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100182512, COSV100182572; called by muse, mutect2, varscan2
- RBMXL3 | c.1994G>A p.G665E | Missense Mutation (SNP) | VAF 87/91 reads (96%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1556559332, COSV57757770; called by muse, mutect2, varscan2
- RECQL4 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs1554895824, COSV56741932, COSV56742746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RECQL4 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100020716; called by muse, mutect2, varscan2
- RECQL5 | c.2717C>G p.S906C | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.319); catalogued as rs368295731; called by muse, mutect2, varscan2
- REG1B | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 104/224 reads (46%) | catalogued as COSV59306959; called by muse, mutect2, varscan2
- RELN | c.9646G>A p.E3216K | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs1444297965; called by muse, mutect2, varscan2
- RFX6 | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.335); catalogued as COSV60586740; called by muse, mutect2, varscan2
- RIC3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV58305309; called by muse, mutect2, varscan2
- RIPK4 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768158256, COSV60185763; called by muse, mutect2, varscan2
- RMND1 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs568717685; called by muse, mutect2, varscan2
- RPAP2 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 106/107 reads (99%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1557634020; called by muse, mutect2, varscan2
- RPL19 | c.112+3G>A | Splice Region (SNP) | VAF 165/359 reads (46%) | catalogued as COSV56636657; called by muse, mutect2, varscan2
- RRBP1 | c.2872C>T p.R958C (on ENST00000377813 / NM_001365613.2; = p.R525C on NM_004587.3) | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs41276394, COSV55695815; called by muse, mutect2, varscan2
- RSF1 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs763953559, COSV57836860; called by muse, mutect2, varscan2
- RSRP1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); catalogued as rs750829736, COSV54562782; called by muse, mutect2, varscan2
- SCN1A | c.5596G>C p.D1866H (on ENST00000303395 / NM_001202435.3; = p.D1855H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM045197, COSV57661006; called by muse, mutect2, varscan2
- SCN3A | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1229864715, COSV51818088; called by muse, mutect2, varscan2
- SCN9A | c.4455G>C p.M1485I (on ENST00000303354; = p.M1474I on NM_002977.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV57603278; called by muse, mutect2, varscan2
- SETD2 | c.1784C>G p.S595* | Nonsense Mutation (SNP) | VAF 35/73 reads (48%) | catalogued as COSV57433188, COSV57436268; called by muse, mutect2, varscan2
- SGPL1 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 83/165 reads (50%) | catalogued as COSV54737888; called by muse, mutect2, varscan2
- SH3D19 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs370259617; called by muse, mutect2, varscan2
- SHANK1 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 73/74 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53245962; called by muse, mutect2, varscan2
- SIRT2 | c.376-7C>T | Splice Region (SNP) | VAF 35/84 reads (42%) | catalogued as rs761795880; called by muse, mutect2, varscan2
- SLC24A1 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 75/143 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1161337628, COSV56051626; called by muse, mutect2, varscan2
- SLC25A35 | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 36/62 reads (58%) | catalogued as rs1229155185, COSV56839868; called by muse, mutect2, varscan2
- SLC2A12 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as rs1432594153; called by muse, mutect2, varscan2
- SLC4A8 | c.1716C>G p.F572L | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.097); catalogued as COSV60657772; called by muse, mutect2, varscan2
- SLC5A12 | c.836A>C p.N279T | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54821833; called by muse, mutect2, varscan2
- SLC6A11 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1412595454; called by muse, mutect2, varscan2
- SLC7A2 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770978455; called by muse, mutect2, varscan2
- SLC8A2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV52637968; called by muse, mutect2
- SLC9C1 | c.2602C>T p.H868Y | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs769513912, COSV59886940, COSV59891175; called by muse, mutect2, varscan2
- SLC9C1 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as COSV59887870; called by muse, mutect2
- SPRY2 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 117/118 reads (99%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.745); catalogued as rs947314080, COSV101001685; called by muse, mutect2, varscan2
- STX16 | c.454G>A p.E152K (on ENST00000371141 / NM_001001433.3; = p.E131K on NM_003763.6) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as rs759831553, COSV56607052; ClinVar: benign; called by muse, mutect2, varscan2
- STYXL2 | c.1674G>C p.K558N | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54805957; called by muse, mutect2, varscan2
- SYBU | c.689G>C p.S230T (on ENST00000276646 / NM_001099754.2; = p.S229T on NM_017786.6) | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs1164153072; called by muse, mutect2, varscan2
- TBC1D8 | c.2533G>A p.D845N | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs748858492; called by muse, mutect2, varscan2
- TCTN2 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as COSV57631528; called by muse, mutect2, varscan2
- TEAD4 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 84/165 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs745449009; called by muse, mutect2, varscan2
- TENM4 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.989); catalogued as COSV53640225; called by muse, mutect2, varscan2
- TMEM63B | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs954585071; called by muse, mutect2
- TNFRSF10B | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs772288130; called by muse, mutect2, varscan2
- TNFRSF6B | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs1218674258, COSV53927551; called by muse, mutect2, varscan2
- TRAF2 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 10/138 reads (7%) | catalogued as COSV56037623, COSV99916667; called by muse, mutect2
- TRAF3 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV61026797; called by muse, mutect2, varscan2
- TRAF5 | c.1334G>C p.R445T | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558150900; called by muse, mutect2, varscan2
- TREM1 | c.612C>G p.F204L | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV55149321; called by muse, mutect2, varscan2
- TREML4 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as rs745575554; called by muse, mutect2, varscan2
- TRIML1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs781586002, COSV100206096; called by muse, mutect2, varscan2
- TSGA10 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100747395; called by muse, mutect2, varscan2
- TTLL13P | c.1199C>G p.S400* | Nonsense Mutation (SNP) | VAF 38/53 reads (72%) | catalogued as COSV60039257; called by muse, mutect2, varscan2
- TUBGCP3 | c.2449-3C>T | Splice Region (SNP) | VAF 50/52 reads (96%) | catalogued as rs1022437083; called by muse, mutect2, varscan2
- TXNRD2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1194387426; called by muse, mutect2, varscan2
- UBA6 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (1); PolyPhen possibly damaging (0.454); catalogued as rs775555934, COSV59177298; called by muse, mutect2, varscan2
- UBE3A | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 136/276 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99217458; called by muse, mutect2, varscan2
- UBLCP1 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs1049202973; called by muse, mutect2, varscan2
- UNC13C | c.4057G>A p.E1353K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs968394323; called by muse, mutect2, varscan2
- UTRN | c.8121G>A p.M2707I | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs761673306; called by muse, mutect2, varscan2
- VSTM5 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV68006836; called by muse, mutect2, varscan2
- WDR17 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV54581815; called by muse, mutect2, varscan2
- WFDC12 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100859104; called by muse, mutect2, varscan2
- WIPF1 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV55815117; called by muse, mutect2, varscan2
- ZFHX3 | c.7573C>T p.P2525S | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs529898113; called by muse, mutect2, varscan2
- ZFHX3 | c.6851G>C p.R2284P | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51739996; called by muse, mutect2, varscan2
- ZFP90 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as rs755853814, COSV68050633; called by muse, mutect2, varscan2
- ZNF287 | c.1825C>G p.Q609E | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.92); catalogued as COSV101209393; called by muse, mutect2
- ZNF318 | c.3887C>T p.S1296F | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs146765143, COSV58931150; called by muse, mutect2, varscan2
- ZNF33B | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV63942914; called by muse, mutect2, varscan2
- ZNF382 | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 139/331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99497644; called by muse, mutect2, varscan2
- ZNF619 | c.675C>A p.F225L | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV100123088; called by muse, mutect2, varscan2
- ZNF831 | c.4373C>T p.S1458L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs771979882, COSV64042483; called by muse, mutect2, varscan2
- ACAN | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRD1 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ADH7 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADRA2B | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFP | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGFG1 | c.1629+1del | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- AK9 | c.4945G>A p.E1649K | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AKAP9 | c.4501C>T p.Q1501* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- ALKBH8 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMBRA1 | c.378+3G>A | Splice Region (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- ANAPC2 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 77/92 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANKRD13C | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ANKRD31 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ANKRD52 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO8 | c.218-8C>T | Splice Region (SNP) | VAF 58/118 reads (49%) | called by muse, varscan2
- ANP32A | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- AP3M2 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- APBB1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APP | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ARHGAP25 | c.406C>G p.Q136E (on ENST00000409202 / NM_001007231.3; = p.Q129E on NM_014882.3) | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ARHGAP44 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ARID2 | c.4735C>T p.Q1579* | Nonsense Mutation (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- ARMCX1 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 62/63 reads (98%) | called by muse, mutect2, varscan2
- ATF6 | c.1320-1G>C p.X440_splice | Splice Site (SNP) | VAF 81/160 reads (51%) | called by muse, mutect2, varscan2
- ATN1 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- BAHCC1 | c.4000G>C p.G1334R | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAZ2B | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- BCAN | c.2342G>A p.G781E | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCAS1 | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BIRC6 | c.12124G>A p.E4042K | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- BRD9 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BTBD9 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 110/245 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- C1orf56 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CCDC127 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC180 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC194 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- CCND2 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCPG1 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CDC45 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CDH12 | c.919A>C p.N307H | Missense Mutation (SNP) | VAF 132/297 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); called by muse, varscan2
- CFAP74 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CFAP91 | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- CHD6 | c.4291G>C p.E1431Q | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CHST14 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- CHST9 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLSTN2 | c.2695G>T p.D899Y | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- CLVS1 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- COL12A1 | c.6125C>G p.S2042W | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL9A2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPOX | c.1364G>C p.*455Sext*75 | Nonstop Mutation (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- CR1L | c.945C>G p.F315L | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRADD | c.309G>C p.L103F | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRHBP | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CRYBG3 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 118/244 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CRYBG3 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 92/179 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CTTNBP2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CXADR | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- CYP2B6 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.293); called by muse, mutect2
- DAZAP2 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DCTN1 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DDX24 | c.1420G>C p.D474H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DEF6 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJB7 | c.846C>G p.F282L | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- DOP1B | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- DST | c.5212C>G p.L1738V | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EDARADD | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, varscan2
- EGR3 | c.1163G>T p.*388Lext*30 | Nonstop Mutation (SNP) | VAF 14/44 reads (32%) | called by muse, varscan2
- EHD3 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- EIF3F | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ELOA | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 88/188 reads (47%) | called by muse, mutect2, varscan2
- EMC2 | c.825G>C p.K275N | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESYT1 | c.807C>A p.T269= | Splice Region (SNP) | VAF 68/121 reads (56%) | called by muse, mutect2, varscan2
- EXOG | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EZH2 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- FAM184A | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- FAM184B | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT2 | c.9488_9489insTT p.A3164Sfs*6 | Frame Shift Ins (INS) | VAF 58/140 reads (41%) | called by mutect2, pindel, varscan2
- FBXL5 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.866); called by muse, varscan2
- FBXW10 | c.3097G>C p.D1033H | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FIBIN | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FMN1 | c.4022C>G p.S1341C (on ENST00000616417 / NM_001277313.2; = p.S1118C on NM_001103184.4) | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, varscan2
- FREM2 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- FREM3 | c.4696G>T p.D1566Y | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.10498G>C p.E3500Q | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FSIP2 | c.15497C>T p.S5166F | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- FSIP2 | c.18127G>A p.E6043K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FUT11 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FUT2 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 65/69 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FZD7 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- GALK1 | c.942C>A p.L314= | Splice Region (SNP) | VAF 49/91 reads (54%) | called by muse, mutect2, varscan2
- GCNT4 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF15 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNAI3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- GNGT1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPC2 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 85/160 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GRIN2B | c.3196C>T p.H1066Y | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HABP2 | c.1213G>C p.D405H | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- HAGH | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 89/90 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HERC2 | c.3302G>C p.G1101A | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HMCN1 | c.6866G>C p.R2289T | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HPX | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- HYAL4 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 119/242 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGLV9-49 | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, varscan2
- IL18RAP | c.1353T>A p.C451* | Nonsense Mutation (SNP) | VAF 41/114 reads (36%) | called by muse, mutect2, varscan2
- IMMT | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.72); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- INPPL1 | c.1871G>C p.S624T | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IQGAP3 | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KCP | c.4174G>A p.A1392T (on ENST00000620378; = p.A1516T on NM_001366122.1) | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- KIRREL2 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHDC8A | c.177G>C p.W59C | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL5 | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- KLK1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 157/165 reads (95%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- KMT2A | c.9290G>C p.G3097A | Missense Mutation (SNP) | VAF 108/245 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- KMT2C | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- LARP1B | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- LETM1 | c.876+8G>C | Splice Region (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2
- LIMK1 | c.1599C>G p.F533L | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMBR1 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LNPEP | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- LRP10 | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- LRP2 | c.6880G>A p.D2294N | Missense Mutation (SNP) | VAF 103/202 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC37A3 | c.3776C>G p.S1259C | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRRC70 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 255/518 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, varscan2
- LTBP2 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- LYAR | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MAMSTR | c.766G>A p.A256T (on ENST00000318083 / NM_001130915.2; = p.A153T on NM_182574.2) | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- MAP3K7CL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP4K4 | c.1829C>T p.S610F (on ENST00000347699 / NM_001242559.2; = p.S579F on NM_145686.3) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- MAPKBP1 | c.2986G>A p.D996N (on ENST00000456763 / NM_001128608.2; = p.D990N on NM_014994.3) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED1 | c.2701C>G p.Q901E | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MFSD4A | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- MKRN1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- MLLT10 | c.1940C>G p.S647* (on ENST00000307729 / NM_001195626.3; = p.S663* on NM_004641.3) | Nonsense Mutation (SNP) | VAF 57/108 reads (53%) | called by muse, mutect2, varscan2
- MORC3 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MRC1 | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- MRC2 | c.4012G>C p.G1338R | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MROH2A | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC12 | c.14399G>C p.S4800T (on ENST00000379442; = p.S4657T on NM_001164462.1) | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated, low confidence (1); called by muse, mutect2, varscan2
- NAGK | c.356-6C>T | Splice Region (SNP) | VAF 76/179 reads (42%) | called by muse, mutect2, varscan2
- NCAPG2 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPTN | c.447G>C p.R149S | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NPY1R | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 187/395 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR5A2 | c.521G>A p.R174K (on ENST00000367362 / NM_205860.3; = p.R128K on NM_003822.5) | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NRG3 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 105/182 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NSD1 | c.7515G>C p.E2505D | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR13C5 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2A14 | c.322C>G p.H108D | Missense Mutation (SNP) | VAF 95/170 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ORC4 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- OSBPL9 | c.1435G>C p.V479L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OVCA2 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PAM | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PARP14 | c.2719C>G p.L907V | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDHGB4 | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 87/168 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PCSK5 | c.5410G>C p.E1804Q | Missense Mutation (SNP) | VAF 164/187 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PDZD2 | c.6651G>T p.R2217S | Missense Mutation (SNP) | VAF 142/278 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PGM2 | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PHF20L1 | c.1722G>C p.K574N | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- PITPNM1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 97/185 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PKN2 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 129/130 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PLEKHG4B | c.382G>C p.E128Q (on ENST00000283426; = p.E484Q on NM_052909.5) | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLR2A | c.675C>G p.F225L | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- POLR2A | c.2253G>C p.K751N | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PPARA | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPARGC1B | c.1059_1060del p.C353* | Frame Shift Del (DEL) | VAF 72/202 reads (36%) | called by pindel, varscan2
- PPL | c.3516G>C p.E1172D | Missense Mutation (SNP) | VAF 167/182 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPP1R15B | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP1R3C | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 66/119 reads (55%) | called by muse, mutect2, varscan2
- PPP6R2 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PRKRIP1 | c.150G>C p.E50D | Missense Mutation (SNP) | VAF 17/375 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.102); called by muse, mutect2
- PRPF8 | c.3313G>T p.E1105* | Nonsense Mutation (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- PRR14L | c.5177C>A p.S1726Y | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); called by muse, mutect2
- PRR15L | c.311G>T p.*104Lext*18 | Nonstop Mutation (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- PTPRK | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB44 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RALGAPA2 | c.3510T>G p.C1170W | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RANBP17 | c.1706C>G p.S569* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- RBM23 | c.560C>G p.S187C (on ENST00000359890 / NM_001077351.2; = p.S171C on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/165 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RGS21 | c.99T>A p.D33E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RIC8B | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RIN3 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RNF115 | c.912C>G p.F304L | Missense Mutation (SNP) | VAF 111/224 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); called by muse, varscan2
- RTTN | c.5842C>T p.H1948Y | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SAMHD1 | c.645C>G p.H215Q | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SAV1 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SCAF4 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.572); called by muse, mutect2
- SCN5A | c.5900C>G p.S1967C (on ENST00000333535 / NM_198056.3; = p.S1966C on NM_000335.5) | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SCO2 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 74/126 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.343); called by muse, mutect2
- SEC16A | c.1160_1163del p.L387Hfs*22 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by mutect2, varscan2
- SERPINA1 | c.537A>C p.K179N | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SETD2 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SGSM1 | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- SH3D19 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- SHISA5 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SIAE | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SKI | c.1546C>G p.P516A | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLAIN2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLFN13 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SMC2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SNRK | c.-106-1G>C | Splice Site (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- SNRNP70 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOCS7 | c.1670C>G p.S557C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPINK14 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRRM4 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STAM2 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STMN2 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 61/164 reads (37%) | called by muse, mutect2, varscan2
- SULT4A1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYBU | c.553A>C p.N185H (on ENST00000276646 / NM_001099754.2; = p.N184H on NM_017786.6) | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- TAAR5 | c.670G>C p.V224L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAL1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TANGO6 | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 52/171 reads (30%) | called by muse, mutect2, varscan2
- TCF19 | c.726G>C p.E242D | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF7L2 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEC | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- TELO2 | c.1134C>G p.D378E | Missense Mutation (SNP) | VAF 30/30 reads (100%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, varscan2
- TELO2 | c.1534C>G p.P512A | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGIF2 | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 83/197 reads (42%) | called by muse, mutect2, varscan2
- TIMELESS | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMA7 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TMEM87B | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TNFSF13B | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TOX3 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPM8 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- TSGA10IP | c.1670G>C p.*557Sext*? | Nonstop Mutation (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- TTC29 | c.853T>G p.L285V | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TTC39B | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TTLL12 | c.981G>C p.Q327H | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UBC | c.220A>G p.R74G | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- UBE2Q1 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBQLN1 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 64/79 reads (81%) | SIFT tolerated (0.22); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- UFSP2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- UMPS | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP1 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- VWA5B2 | c.2930C>T p.A977V | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- WDR7 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDR74 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- WLS | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 106/226 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- WRNIP1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.651); called by muse, mutect2
- ZBTB43 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 101/127 reads (80%) | called by muse, mutect2, varscan2
- ZFAND4 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZFAT | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); called by muse, varscan2
- ZFHX3 | c.8393C>T p.T2798I | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZGRF1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ZIC5 | c.1934C>G p.S645C | Missense Mutation (SNP) | VAF 51/51 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF195 | c.787C>A p.Q263K (on ENST00000399602 / NM_001130520.3; = p.Q191K on NM_007152.5) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ZNF277 | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ZNF318 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZNF41 | c.2184C>A p.F728L | Missense Mutation (SNP) | VAF 75/76 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZNF430 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF641 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZP4 | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZSWIM6 | c.1416G>C p.W472C | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC1 | c.1260C>T p.V420= | Silent (SNP) | VAF 31/31 reads (100%) | catalogued as rs755996982; called by muse, mutect2, varscan2
- ACACB | c.2766C>T p.Y922= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs759904403; called by muse, mutect2, varscan2
- ACAN | c.690G>A p.V230= | Silent (SNP) | VAF 171/351 reads (49%) | catalogued as rs1159686392; called by muse, mutect2, varscan2
- ACP6 | c.1245C>T p.L415= | Silent (SNP) | VAF 121/274 reads (44%) | called by muse, mutect2, varscan2
- ADAM15 | c.111G>A p.E37= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1431375793, COSV55062992; called by muse, mutect2, varscan2
- ADAMTS14 | c.3453C>T p.L1151= | Silent (SNP) | VAF 130/284 reads (46%) | catalogued as rs144890013; called by muse, mutect2, varscan2
- AMN | c.330C>T p.F110= | Silent (SNP) | VAF 87/180 reads (48%) | called by muse, mutect2, varscan2
- ANKRD31 | c.270C>T p.S90= | Silent (SNP) | VAF 45/79 reads (57%) | catalogued as rs375356487; called by muse, mutect2, varscan2
- ARHGAP33 | c.2703C>T p.P901= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs752746668; called by muse, mutect2, varscan2
- ARHGEF2 | c.2691C>T p.F897= (on ENST00000361247 / NM_001162383.2; = p.F869= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 46/107 reads (43%) | called by muse, mutect2, varscan2
- ARIH1 | c.1446C>G p.L482= | Silent (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- ARVCF | c.2235C>T p.L745= | Silent (SNP) | VAF 55/123 reads (45%) | called by muse, mutect2, varscan2
- ASAP1 | c.3207G>A p.V1069= | Silent (SNP) | VAF 76/164 reads (46%) | called by muse, mutect2, varscan2
- ASTE1 | c.876C>G p.L292= | Silent (SNP) | VAF 74/181 reads (41%) | called by muse, mutect2, varscan2
- ATP10A | c.444C>T p.F148= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1298930750; called by muse, mutect2, varscan2
- ATP2A2 | c.1335C>T p.L445= | Silent (SNP) | VAF 96/194 reads (49%) | catalogued as rs747229006, COSV100428647; called by muse, mutect2, varscan2
- BAD | c.72C>T p.P24= | Silent (SNP) | VAF 97/165 reads (59%) | called by muse, mutect2, varscan2
- BCAT2 | c.501C>G p.L167= | Silent (SNP) | VAF 128/130 reads (98%) | called by muse, mutect2, varscan2
- BTBD8 | c.2142G>A p.G714= (on ENST00000636805 / NM_001376131.1; = p.G201= on NM_015237.4) | Silent (SNP) | VAF 93/93 reads (100%) | called by muse, mutect2, varscan2
- C10orf71 | c.609C>T p.S203= | Silent (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- C11orf54 | c.555G>A p.V185= | Silent (SNP) | VAF 112/231 reads (48%) | catalogued as rs762763791; called by muse, mutect2, varscan2
- CADPS | c.804G>C p.L268= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV51885147; called by muse, mutect2, varscan2
- CCDC110 | c.1461G>A p.K487= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs1201365178, COSV100294000; called by muse, mutect2
- CCDC153 | c.609G>A p.L203= | Silent (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- CCDC68 | c.657C>G p.L219= | Silent (SNP) | VAF 36/64 reads (56%) | catalogued as rs774082821; called by muse, mutect2, varscan2
- CELSR1 | c.9015G>A p.Q3005= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- CELSR2 | c.5973C>T p.F1991= | Silent (SNP) | VAF 43/43 reads (100%) | catalogued as rs778661369, COSV54766642; called by muse, mutect2, varscan2
- CHRNA4 | c.633C>T p.I211= | Silent (SNP) | VAF 152/333 reads (46%) | catalogued as rs769813725; called by muse, mutect2, varscan2
- CIT | c.5685C>T p.V1895= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs1327193921; called by muse, mutect2, varscan2
- CLDN15 | c.162C>T p.T54= | Silent (SNP) | VAF 81/178 reads (46%) | catalogued as rs1267714270, COSV99778951; called by muse, mutect2, varscan2
- CLEC14A | c.51G>C p.G17= | Silent (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- COBL | c.1086G>A p.K362= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV54357649; called by muse, mutect2
- COL12A1 | c.8769C>T p.F2923= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV59406766; called by muse, mutect2, varscan2
- CPNE3 | c.1290G>A p.V430= | Silent (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- CTPS1 | c.1002C>A p.I334= | Silent (SNP) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- CUL9 | c.30C>T p.L10= | Silent (SNP) | VAF 63/115 reads (55%) | catalogued as rs746722983; called by muse, mutect2, varscan2
- CYP1B1 | c.831G>A p.L277= | Silent (SNP) | VAF 65/154 reads (42%) | catalogued as COSV99572874; called by muse, mutect2, varscan2
- CYP26B1 | c.924C>T p.L308= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs760382196; called by muse, mutect2, varscan2
- DHRSX | c.498G>C p.L166= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- DLX4 | c.369C>T p.I123= (on ENST00000240306 / NM_138281.3; = p.I51= on NM_001934.3) | Silent (SNP) | VAF 72/161 reads (45%) | catalogued as rs767672602; called by muse, mutect2, varscan2
- DMXL2 | c.5748C>A p.A1916= | Silent (SNP) | VAF 89/215 reads (41%) | called by muse, mutect2, varscan2
- DNAH9 | c.30C>T p.L10= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs781715550; called by muse, varscan2
- DNAJC13 | c.3153G>A p.L1051= | Silent (SNP) | VAF 52/112 reads (46%) | called by muse, mutect2, varscan2
- DNAJC6 | c.15G>A p.E5= | Silent (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- DOCK6 | c.3297G>C p.L1099= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- DOT1L | c.1191G>A p.K397= | Silent (SNP) | VAF 73/145 reads (50%) | catalogued as rs1359407823; called by muse, mutect2, varscan2
- DUOX1 | c.2439C>G p.L813= | Silent (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- DYRK4 | c.319C>T p.L107= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV50537884; called by muse, mutect2, varscan2
- E4F1 | c.705C>G p.L235= | Silent (SNP) | VAF 28/29 reads (97%) | called by muse, mutect2, varscan2
- EDARADD | c.24G>A p.Q8= | Silent (SNP) | VAF 114/204 reads (56%) | called by muse, varscan2
- EIF2AK3 | c.2253C>T p.I751= | Silent (SNP) | VAF 89/178 reads (50%) | catalogued as COSV57549199; called by muse, mutect2, varscan2
- ENTPD6 | c.108G>A p.G36= | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as rs1225569056; called by muse, mutect2, varscan2
- ERLEC1 | c.1068C>T p.F356= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs1185723691; called by muse, mutect2, varscan2
- F5 | c.6430C>T p.L2144= | Silent (SNP) | VAF 100/212 reads (47%) | called by muse, mutect2, varscan2
- FAN1 | c.1149G>A p.L383= | Silent (SNP) | VAF 75/163 reads (46%) | called by muse, mutect2, varscan2
- FO681492.1 | c.1206C>T p.F402= | Silent (SNP) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- FRY | c.8586G>A p.L2862= | Silent (SNP) | VAF 77/77 reads (100%) | catalogued as COSV66511411; called by muse, mutect2, varscan2
- GABRG2 | c.1515C>G p.L505= (on ENST00000361925 / NM_001375343.1; = p.L465= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV100729696; called by muse, mutect2, varscan2
- GLRX2 | c.15C>A p.R5= | Silent (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- GPATCH2 | c.472C>T p.L158= | Silent (SNP) | VAF 101/202 reads (50%) | called by muse, mutect2, varscan2
- HAPLN4 | c.69C>T p.L23= | Silent (SNP) | VAF 74/139 reads (53%) | called by muse, mutect2, varscan2
- HNRNPU | c.60C>T p.L20= | Silent (SNP) | VAF 116/202 reads (57%) | called by muse, mutect2, varscan2
- HPX | c.798G>A p.L266= | Silent (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.99C>G p.P33= | Silent (SNP) | VAF 76/110 reads (69%) | catalogued as rs771235208; called by muse, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 52/60 reads (87%) | catalogued as rs1233195687; called by muse, varscan2
- IGLL5 | c.81G>A p.L27= | Silent (SNP) | VAF 34/34 reads (100%) | catalogued as rs56055217, COSV73249379; called by muse, varscan2
- IGLL5 | c.84G>A p.L28= | Silent (SNP) | VAF 32/32 reads (100%) | catalogued as rs772288552, COSV73248990, COSV73251143; called by muse, varscan2
- IGLV9-49 | c.192G>C p.R64= | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as rs766538688; called by muse, varscan2
- IHH | c.762G>A p.L254= | Silent (SNP) | VAF 69/132 reads (52%) | catalogued as COSV55392824, COSV55393387; called by muse, mutect2, varscan2
- INSRR | c.2190G>A p.V730= | Silent (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- INTS10 | c.1194C>T p.V398= | Silent (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- IPO4 | c.42G>A p.L14= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs780508209; called by muse, mutect2, varscan2
- IRX1 | c.891G>A p.L297= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs1459154453; called by muse, mutect2, varscan2
- ITGA4 | c.231C>T p.L77= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs778370219; called by muse, mutect2, varscan2
- ITGA7 | c.3345C>T p.P1115= (on ENST00000555728; = p.P1071= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/155 reads (46%) | catalogued as rs559955065; called by muse, mutect2, varscan2
- KCNMA1 | c.1962C>T p.I654= | Silent (SNP) | VAF 45/76 reads (59%) | called by muse, mutect2, varscan2
- KCTD8 | c.723C>T p.I241= | Silent (SNP) | VAF 60/109 reads (55%) | catalogued as rs1316891381, COSV63585841, COSV63593698; called by muse, mutect2, varscan2
- KDM8 | c.366C>T p.V122= | Silent (SNP) | VAF 63/119 reads (53%) | called by muse, mutect2, varscan2
- KIF7 | c.3330C>A p.L1110= | Silent (SNP) | VAF 116/237 reads (49%) | called by muse, mutect2, varscan2
- KLHL33 | c.960G>A p.L320= | Silent (SNP) | VAF 79/170 reads (46%) | called by muse, mutect2, varscan2
- KRT12 | c.1248G>A p.L416= | Silent (SNP) | VAF 49/91 reads (54%) | catalogued as rs768827325; called by muse, mutect2, varscan2
- KRTAP10-12 | c.561C>T p.S187= | Silent (SNP) | VAF 54/106 reads (51%) | called by muse, mutect2, varscan2
- LAMA4 | c.2622G>A p.L874= (on ENST00000230538 / NM_001105206.3; = p.L867= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- LRBA | c.4749C>T p.F1583= | Silent (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- LRRC3 | c.645C>T p.F215= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs371240605; called by muse, mutect2, varscan2
- LY6K | c.246G>A p.A82= | Silent (SNP) | VAF 102/211 reads (48%) | catalogued as rs782387825, COSV52832165; called by muse, mutect2, varscan2
- LY75-CD302 | c.5314C>T p.L1772= | Silent (SNP) | VAF 98/209 reads (47%) | catalogued as COSV52033695, COSV52033788; called by muse, mutect2, varscan2
- MAP3K6 | c.639C>T p.L213= | Silent (SNP) | VAF 56/115 reads (49%) | called by muse, mutect2, varscan2
- MARS1 | c.1497C>G p.L499= | Silent (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- MDN1 | c.12753C>T p.I4251= | Silent (SNP) | VAF 70/150 reads (47%) | called by muse, mutect2, varscan2
- MED13L | c.5172C>T p.L1724= | Silent (SNP) | VAF 67/134 reads (50%) | called by muse, mutect2, varscan2
- MEOX2 | c.786G>A p.V262= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as rs1252943001, COSV56289324; called by muse, mutect2, varscan2
- MOCOS | c.1923C>T p.I641= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs200601583; called by muse, mutect2, varscan2
- MSI1 | c.924G>C p.L308= | Silent (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- MUC19 | c.1335G>A p.S445= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs897536763; called by muse, mutect2, varscan2
- MXRA5 | c.6594C>T p.I2198= | Silent (SNP) | VAF 85/92 reads (92%) | catalogued as COSV99476055; called by muse, mutect2, varscan2
- MYO10 | c.1845C>T p.F615= | Silent (SNP) | VAF 67/122 reads (55%) | catalogued as COSV72562871; called by muse, mutect2, varscan2
- MYORG | c.1821C>T p.F607= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as COSV99898748; called by muse, mutect2, varscan2
- NCKAP5 | c.3261G>C p.G1087= | Silent (SNP) | VAF 48/89 reads (54%) | called by muse, mutect2, varscan2
- NEK9 | c.189C>T p.F63= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs1462772610; called by muse, mutect2, varscan2
- NODAL | c.1041C>G p.L347= | Silent (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- NOS1AP | c.1344C>G p.L448= | Silent (SNP) | VAF 114/214 reads (53%) | called by muse, mutect2, varscan2
- NOTCH2 | c.2352G>A p.K784= | Silent (SNP) | VAF 71/150 reads (47%) | catalogued as rs782553837; called by muse, mutect2, varscan2
- NPFFR2 | c.882G>A p.V294= | Silent (SNP) | VAF 69/166 reads (42%) | catalogued as rs758518287; called by muse, mutect2, varscan2
- NPHS1 | c.1527C>T p.F509= | Silent (SNP) | VAF 76/115 reads (66%) | catalogued as COSV62286469; called by muse, mutect2, varscan2
- NWD2 | c.1662G>A p.Q554= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs1008787026; called by muse, mutect2, varscan2
- OCSTAMP | c.609C>T p.V203= | Silent (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- OR2W1 | c.684G>T p.T228= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as COSV65851448; called by muse, mutect2, varscan2
- P3H2 | c.1644G>A p.L548= | Silent (SNP) | VAF 76/158 reads (48%) | catalogued as COSV60020114; called by muse, varscan2
- PAQR9 | c.984C>T p.Y328= | Silent (SNP) | VAF 86/162 reads (53%) | catalogued as rs959919566, COSV61417788; called by muse, mutect2, varscan2
- PCDHGA10 | c.144C>T p.F48= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV53917819; called by muse, mutect2, varscan2
- PCNX1 | c.6792G>A p.R2264= | Silent (SNP) | VAF 64/109 reads (59%) | catalogued as rs766532689, COSV53089059; called by muse, mutect2, varscan2
- PEG3 | c.1302C>T p.L434= | Silent (SNP) | VAF 214/225 reads (95%) | catalogued as COSV99689563; called by muse, mutect2, varscan2
- PLD5 | c.198G>A p.Q66= (on ENST00000442594; = p.Q4= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/166 reads (46%) | catalogued as COSV59151390; called by muse, mutect2, varscan2
- PLXNC1 | c.357C>T p.L119= | Silent (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- PNMA3 | c.594G>A p.E198= | Silent (SNP) | VAF 48/50 reads (96%) | called by mutect2, varscan2
- POLR3A | c.2088C>T p.F696= | Silent (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- POU2AF1 | c.96G>A p.L32= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as rs1373182827; called by muse, mutect2, varscan2
- POU3F3 | c.354G>C p.A118= | Silent (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- PRKCD | c.615C>T p.I205= | Silent (SNP) | VAF 73/131 reads (56%) | catalogued as rs782677594; called by muse, mutect2, varscan2
- PRPF31 | c.477C>G p.L159= | Silent (SNP) | VAF 173/184 reads (94%) | called by muse, mutect2, varscan2
- PRR4 | c.18C>G p.L6= | Silent (SNP) | VAF 120/257 reads (47%) | called by muse, mutect2, varscan2
- PSMD3 | c.57C>T p.P19= | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- PURB | c.429C>T p.F143= | Silent (SNP) | VAF 65/138 reads (47%) | catalogued as COSV67480362; called by muse, mutect2, varscan2
- RASEF | c.1101C>T p.F367= | Silent (SNP) | VAF 102/115 reads (89%) | catalogued as COSV100907018; called by muse, mutect2
- RBM19 | c.2346G>A p.R782= | Silent (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- RHAG | c.21C>G p.L7= | Silent (SNP) | VAF 156/301 reads (52%) | called by muse, mutect2, varscan2
- RP2 | c.690G>A p.K230= | Silent (SNP) | VAF 64/65 reads (98%) | called by muse, mutect2, varscan2
- RPS2 | c.819C>T p.L273= | Silent (SNP) | VAF 36/36 reads (100%) | catalogued as rs759648257, COSV51910996; called by muse, mutect2, varscan2
- RYR2 | c.14640C>T p.V4880= | Silent (SNP) | VAF 53/116 reads (46%) | called by muse, mutect2, varscan2
- RYR3 | c.5433C>T p.L1811= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SALL4 | c.972G>A p.P324= | Silent (SNP) | VAF 64/123 reads (52%) | catalogued as rs149482138; called by muse, mutect2, varscan2
- SCP2D1 | c.198C>T p.V66= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- SH3BP4 | c.1803C>G p.L601= | Silent (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- SHPRH | c.2253G>A p.V751= | Silent (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4497G>A p.V1499= | Silent (SNP) | VAF 94/104 reads (90%) | catalogued as COSV101098779; called by muse, mutect2, varscan2
- SIPA1L3 | c.492C>T p.L164= | Silent (SNP) | VAF 93/158 reads (59%) | catalogued as rs1568538895, COSV99729911; called by muse, mutect2, varscan2
- SIRT4 | c.639G>A p.R213= | Silent (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- SKI | c.444C>T p.I148= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as rs1391345174; called by muse, mutect2, varscan2
- SLC10A5 | c.741G>C p.L247= | Silent (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- SLC16A8 | c.150C>T p.F50= | Silent (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- SLC18A3 | c.282G>C p.T94= | Silent (SNP) | VAF 71/155 reads (46%) | catalogued as COSV60330063; called by muse, mutect2, varscan2
- SLC26A6 | c.2238G>A p.P746= | Silent (SNP) | VAF 60/110 reads (55%) | catalogued as rs762099048; called by muse, mutect2, varscan2
- SLC39A9 | c.12C>T p.F4= | Silent (SNP) | VAF 112/212 reads (53%) | catalogued as COSV50362689; called by muse, mutect2, varscan2
- SLC44A5 | c.780G>A p.L260= | Silent (SNP) | VAF 90/196 reads (46%) | called by muse, varscan2
- SLC9C2 | c.2217C>G p.L739= | Silent (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.1965C>G p.L655= | Silent (SNP) | VAF 69/158 reads (44%) | called by muse, mutect2, varscan2
- SMC1B | c.1956C>T p.I652= | Silent (SNP) | VAF 129/254 reads (51%) | called by muse, varscan2
- STYK1 | c.900G>C p.L300= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV50012862; called by muse, mutect2, varscan2
- SYT4 | c.783C>T p.L261= | Silent (SNP) | VAF 62/119 reads (52%) | called by muse, mutect2, varscan2
- TAP1 | c.1872G>A p.L624= | Silent (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- TBC1D16 | c.2112C>T p.H704= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as rs749627787, COSV59988807; called by muse, mutect2, varscan2
- TBX3 | c.1791C>T p.F597= (on ENST00000257566 / NM_016569.4; = p.F577= on NM_005996.4) | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV57472075; called by muse, mutect2, varscan2
- TCHH | c.1467G>A p.L489= | Silent (SNP) | VAF 238/395 reads (60%) | called by muse, mutect2, varscan2
- TDRD6 | c.5622G>A p.P1874= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs549944300; called by muse, mutect2, varscan2
- TENT5C | c.153C>T p.I51= | Silent (SNP) | VAF 44/156 reads (28%) | catalogued as rs374748531; called by muse, mutect2, varscan2
- TEX49 | c.219C>T p.F73= | Silent (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- THBS4 | c.2448G>A p.T816= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as rs751672404, COSV63469291; called by muse, mutect2, varscan2
- THEMIS2 | c.465C>T p.V155= | Silent (SNP) | VAF 58/113 reads (51%) | called by muse, mutect2, varscan2
- THEMIS2 | c.873C>T p.V291= | Silent (SNP) | VAF 56/106 reads (53%) | called by muse, mutect2, varscan2
- TICRR | c.2580A>G p.L860= | Silent (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- TLK1 | c.390G>A p.Q130= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as rs767889130; called by muse, mutect2, varscan2
- TMEM132A | c.2715G>A p.L905= (on ENST00000453848 / NM_178031.3; = p.L906= on NM_017870.4) | Silent (SNP) | VAF 39/41 reads (95%) | called by muse, mutect2, varscan2
- TMEM169 | c.366C>T p.V122= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV99824522; called by muse, mutect2, varscan2
- TPO | c.1488G>A p.T496= | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as rs758020153, COSV100219517, COSV61101552; called by muse, mutect2
- UBC | c.129G>C p.L43= | Silent (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- UCHL1 | c.39G>A p.L13= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs748451000; called by muse, mutect2, varscan2
- UNC5D | c.708C>T p.I236= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as rs764908615, COSV54767563, COSV54777646; called by muse, mutect2, varscan2
- VASP | c.99C>T p.F33= | Silent (SNP) | VAF 180/192 reads (94%) | called by muse, mutect2, varscan2
- WAPL | c.2154C>T p.L718= | Silent (SNP) | VAF 113/245 reads (46%) | catalogued as COSV99556261; called by muse, varscan2
- WAPL | c.1194C>T p.L398= | Silent (SNP) | VAF 95/185 reads (51%) | called by muse, mutect2, varscan2
- WIPF3 | c.276G>A p.A92= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs773534556; called by muse, mutect2, varscan2
- XRN2 | c.1296C>T p.F432= | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as COSV65870885; called by muse, mutect2, varscan2
- ZFHX3 | c.7233G>A p.A2411= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as rs769762758, COSV51718668; called by muse, mutect2, varscan2
- ZFP42 | c.504C>T p.L168= | Silent (SNP) | VAF 115/218 reads (53%) | catalogued as rs1262935826; called by muse, mutect2, varscan2
- ZFYVE26 | c.4039C>T p.L1347= | Silent (SNP) | VAF 99/190 reads (52%) | catalogued as COSV61325647; called by muse, mutect2, varscan2
- ZIC4 | c.117C>T p.S39= | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as rs373963441; called by muse, mutect2, varscan2
- ZNF407 | c.2997C>T p.F999= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as rs777370703, COSV55266337; called by muse, varscan2
- ZNF407 | c.3795C>T p.L1265= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs764382754, COSV55253771; called by muse, mutect2, varscan2
- ZNF816 | c.267G>A p.T89= | Silent (SNP) | VAF 236/244 reads (97%) | catalogued as rs746147660, COSV54410740; called by muse, mutect2
- ZNRF3 | c.1587C>T p.F529= (on ENST00000544604 / NM_001206998.2; = p.F429= on NM_032173.3) | Silent (SNP) | VAF 68/136 reads (50%) | called by muse, mutect2, varscan2
- ABCA11P | n.1454C>G | RNA (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- ABCB9 | c.*774C>G | 3'UTR (SNP) | VAF 73/176 reads (41%) | called by muse, mutect2, varscan2
- ABCC5 | c.592-2001C>A | Intron (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- ABHD3 | c.-70C>T | 5'UTR (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- ABRACL | c.*237G>C | 3'UTR (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- AC004593.2 | c.*1301G>T | 3'UTR (SNP) | VAF 39/61 reads (64%) | called by muse, mutect2, varscan2
- AC007342.3 | n.678C>G | RNA (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- AC025538.1 | n.1466C>T | RNA (SNP) | VAF 54/100 reads (54%) | catalogued as rs1448519312; called by muse, mutect2, varscan2
- AC025884.2 | n.511G>A | RNA (SNP) | VAF 5/18 reads (28%) | catalogued as rs1041139507; called by muse, mutect2, varscan2
- AC073310.1 | n.810G>A | RNA (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- AC092718.8 | c.*1629G>C | 3'UTR (SNP) | VAF 36/38 reads (95%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149813 G>A | 5'Flank (SNP) | VAF 38/38 reads (100%) | catalogued as rs747517492; called by muse, mutect2, varscan2
- AC107871.1 | c.84-8556C>T | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as rs1025631823; called by muse, mutect2
- ACTN2 | c.*1418A>T | 3'UTR (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.1091-52C>T | Intron (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- ADAMTS7P1 | n.25G>A | RNA (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.1464-555C>A | Intron (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.1464-556C>A | Intron (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- ADGRF1 | c.*134C>G | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:62071677 C>T | 3'Flank (SNP) | VAF 56/124 reads (45%) | called by muse, varscan2
- ADGRL3 | chr4:62071722 C>T | 3'Flank (SNP) | VAF 60/99 reads (61%) | called by muse, varscan2
- ADH1B | c.*1459G>C | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- ADIPOR1 | c.*441C>T | 3'UTR (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- ADORA1 | c.*542G>T | 3'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- AFDN | chr6:167826195 C>G | 5'Flank (SNP) | VAF 260/537 reads (48%) | called by muse, mutect2, varscan2
- AGA | c.*644G>C | 3'UTR (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+323C>T | Intron (SNP) | VAF 34/61 reads (56%) | catalogued as rs1031112613, COSV57247503; called by muse, mutect2, varscan2
- AGXT2 | c.675+50G>C | Intron (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2
- AKAP13 | c.*851C>T | 3'UTR (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1186C>T | Intron (SNP) | VAF 50/92 reads (54%) | called by muse, mutect2, varscan2
- ALDH1B1 | c.*713C>T | 3'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.*3478G>A | 3'UTR (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100708793; called by muse, mutect2, varscan2
- ALG14 | c.*279G>A | 3'UTR (SNP) | VAF 21/22 reads (95%) | called by muse, mutect2, varscan2
- ALPK2 | c.*366C>G | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- AMN | c.513+45C>T | Intron (SNP) | VAF 28/58 reads (48%) | catalogued as rs1252699683; called by muse, mutect2, varscan2
- AMOTL1 | c.*5653G>T | 3'UTR (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- AMZ1 | c.-148C>T | 5'UTR (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- ANKS1A | c.-22C>T | 5'UTR (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- AP4E1 | c.*2759G>A | 3'UTR (SNP) | VAF 35/71 reads (49%) | catalogued as rs1269582815; called by muse, mutect2, varscan2
- AP5Z1 | c.-20C>T | 5'UTR (SNP) | VAF 23/54 reads (43%) | catalogued as rs1373905500; called by muse, mutect2, varscan2
- APBB1IP | c.453+167C>T | Intron (SNP) | VAF 79/185 reads (43%) | called by muse, mutect2, varscan2
- APOBEC3H | c.150+49C>T | Intron (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2
- ARF1 | c.*444G>C | 3'UTR (SNP) | VAF 50/86 reads (58%) | called by muse, mutect2, varscan2
- ARHGAP11B | c.-559G>C | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP11B | c.660+49G>C | Intron (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- ARHGDIB | c.*107G>A | 3'UTR (SNP) | VAF 23/40 reads (58%) | catalogued as COSV99844229; called by muse, mutect2, varscan2
- ARHGEF12 | c.*1103G>C | 3'UTR (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621618 C>T | 3'Flank (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914457 G>C | 5'Flank (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.*503G>A | 3'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- ARID5B | c.*1767G>C | 3'UTR (SNP) | VAF 56/102 reads (55%) | called by muse, varscan2
- ARMC10 | chr7:103075132 C>T | 5'Flank (SNP) | VAF 90/204 reads (44%) | catalogued as rs1319162167; called by muse, mutect2, varscan2
- ARMH1 | c.1128+66C>T | Intron (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- ARSB | chr5:78985558 C>A | 5'Flank (SNP) | VAF 20/54 reads (37%) | called by mutect2, varscan2
- ARSJ | c.*1018G>A | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- ASCC3 | c.241+7428del | Intron (DEL) | VAF 96/251 reads (38%) | called by mutect2, pindel, varscan2
- ASPA | c.*1100G>C | 3'UTR (SNP) | VAF 105/214 reads (49%) | called by muse, mutect2, varscan2
- ATAD2B | c.*3193C>T | 3'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- ATAD3A | chr1:1509328 G>A | 5'Flank (SNP) | VAF 32/95 reads (34%) | catalogued as rs751867877; called by muse, mutect2, varscan2
- ATG14 | c.*569C>T | 3'UTR (SNP) | VAF 79/158 reads (50%) | called by muse, mutect2, varscan2
- ATL3 | c.*1352C>G | 3'UTR (SNP) | VAF 32/55 reads (58%) | catalogued as rs1418648865; called by muse, mutect2, varscan2
- ATP5PB | c.*1135G>C | 3'UTR (SNP) | VAF 11/11 reads (100%) | called by muse, mutect2, varscan2
- ATP7B | c.*1112C>G | 3'UTR (SNP) | VAF 88/88 reads (100%) | called by muse, mutect2, varscan2
- ATP8A2 | c.-36C>G | 5'UTR (SNP) | VAF 28/29 reads (97%) | called by muse, mutect2, varscan2
- ATP9A | c.*3973G>A | 3'UTR (SNP) | VAF 50/98 reads (51%) | called by muse, mutect2, varscan2
- ATPSCKMT | c.307-273C>G | Intron (SNP) | VAF 66/154 reads (43%) | called by muse, mutect2, varscan2
- ATXN7 | c.*2176G>C | 3'UTR (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- ATXN7L3B | c.*1236C>T | 3'UTR (SNP) | VAF 27/64 reads (42%) | catalogued as rs1031155888, COSV101576279, COSV101576314; called by muse, mutect2, varscan2
- AUTS2 | c.*945G>A | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- BCAN | c.*287C>G | 3'UTR (SNP) | VAF 54/125 reads (43%) | called by muse, mutect2, varscan2
- BCAS1 | chr20:53940708 C>T | 3'Flank (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- BCAS1 | chr20:53941459 C>G | 3'Flank (SNP) | VAF 82/158 reads (52%) | called by muse, mutect2, varscan2
- BCAT1 | c.*4539G>C | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- BCAT1 | c.7-987G>A | Intron (SNP) | VAF 88/170 reads (52%) | called by muse, mutect2, varscan2
- BCL7B | c.437-16C>G | Intron (SNP) | VAF 54/126 reads (43%) | called by muse, mutect2, varscan2
- BDP1 | c.*234C>T | 3'UTR (SNP) | VAF 28/52 reads (54%) | called by muse, varscan2
- BDP1 | c.*272C>T | 3'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, varscan2
- BDP1 | c.*273T>A | 3'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, varscan2
- BEGAIN | c.*655C>T | 3'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- BEND3 | c.*769G>A | 3'UTR (SNP) | VAF 80/142 reads (56%) | called by muse, mutect2, varscan2
- BEND4 | c.*5270C>G | 3'UTR (SNP) | VAF 24/46 reads (52%) | catalogued as rs1468860359; called by muse, mutect2, varscan2
- BEST2 | c.*125C>T | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- BIN3 | c.339-1172C>T | Intron (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- BMPR1B | chr4:95157134 C>G | 3'Flank (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- C16orf70 | c.661+31C>G | Intron (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- C1orf229 | n.1278G>A | RNA (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- C1orf229 | n.1094G>A | RNA (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- C2CD2L | c.*1952C>T | 3'UTR (SNP) | VAF 76/160 reads (48%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+1233G>C | Intron (SNP) | VAF 49/90 reads (54%) | catalogued as COSV53798935; called by muse, mutect2, varscan2
- C3orf35 | chr3:37417601 G>C | 3'Flank (SNP) | VAF 66/125 reads (53%) | called by muse, mutect2, varscan2
- C5orf24 | c.*252G>C | 3'UTR (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- C5orf24 | c.*452G>A | 3'UTR (SNP) | VAF 48/86 reads (56%) | called by muse, mutect2, varscan2
- C5orf24 | c.*1341G>C | 3'UTR (SNP) | VAF 39/64 reads (61%) | called by muse, mutect2, varscan2
- C6orf99 | n.32G>A | RNA (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- C8orf34 | c.607+1128C>T | Intron (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- C9orf163 | n.1721C>T | RNA (SNP) | VAF 36/49 reads (73%) | called by muse, mutect2, varscan2
- C9orf62 | n.184T>G | RNA (SNP) | VAF 54/65 reads (83%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.*682G>A | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2
- CACNB4 | c.148-25G>C | Intron (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- CARMIL3 | c.2481-40G>A | Intron (SNP) | VAF 29/72 reads (40%) | catalogued as rs1275686916; called by muse, mutect2, varscan2
- CBLB | c.*2593G>A | 3'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- CCDC116 | c.1203+198C>T | Intron (SNP) | VAF 94/190 reads (49%) | called by muse, mutect2, varscan2
- CCDC149 | c.*824C>T | 3'UTR (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- CCDC185 | c.*88G>C | 3'UTR (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- CCL16 | c.*482C>T | 3'UTR (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- CCNH | c.934-168G>C | Intron (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- CCNY | c.264+29C>T | Intron (SNP) | VAF 90/181 reads (50%) | catalogued as rs1406204979; called by muse, mutect2, varscan2
- CDK15 | c.1199-2267G>C | Intron (SNP) | VAF 54/178 reads (30%) | called by muse, mutect2, varscan2
- CDKN2B | c.-334G>A | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- CDSN | c.*518C>T | 3'UTR (SNP) | VAF 25/73 reads (34%) | catalogued as rs1172584341; called by muse, mutect2, varscan2
- CELSR1 | c.*1838C>T | 3'UTR (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- CEMIP | chr15:80952113 G>A | 3'Flank (SNP) | VAF 15/34 reads (44%) | catalogued as rs563404087; called by muse, mutect2, varscan2
- CENPU | c.-17G>C | 5'UTR (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2
- CEP112 | c.2395-55G>C | Intron (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- CEP41 | c.277+134C>T | Intron (SNP) | VAF 40/91 reads (44%) | catalogued as rs950543630; called by muse, mutect2, varscan2
- CEP41 | c.98-4906C>T | Intron (SNP) | VAF 55/125 reads (44%) | called by muse, mutect2, varscan2
- CEP43 | c.*848G>A | 3'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- CEP97 | c.*799C>A | 3'UTR (SNP) | VAF 56/100 reads (56%) | called by muse, varscan2
- CEP97 | c.*862C>A | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, varscan2
- CFHR3 | c.613+582C>G | Intron (SNP) | VAF 157/327 reads (48%) | catalogued as rs566236083; called by muse, mutect2, varscan2
- CGGBP1 | c.*1661G>A | 3'UTR (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- CGGBP1 | c.-23-889G>C | Intron (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- CHEK2P2 | n.322C>G | RNA (SNP) | VAF 107/625 reads (17%) | called by muse, mutect2, varscan2
- CIPC | c.*462G>C | 3'UTR (SNP) | VAF 63/128 reads (49%) | called by muse, mutect2, varscan2
- CKS2 | c.-85G>A | 5'UTR (SNP) | VAF 8/112 reads (7%) | catalogued as rs1367633205; called by muse, mutect2
551 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 551 other) are not listed here.
